Somatic mutation profile of tumor specimen TCGA-AG-A02N-01A (aliquot TCGA-AG-A02N-01A-11W-A096-10) from TCGA case TCGA-AG-A02N, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 67.6 years (24,687 days).
Specimen TCGA-AG-A02N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fdbf9c9-e85c-4b22-96c1-7f1eb5b662fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A02N-11A (Solid Tissue Normal), aliquot TCGA-AG-A02N-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54832cc9-391f-4ab1-ad2a-9b0e97ff35f0

The open-access MAF lists 1,353 somatic variants for this specimen: 1,012 protein-altering or splice-affecting, 321 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 712, Silent 321, Frame Shift Del 166, Nonsense Mutation 60, Frame Shift Ins 33, Splice Site 15, In Frame Del 14, Intron 14, Splice Region 10, 3'Flank 3, Translation Start Site 2, RNA 2.

Variants (750 of 1,353; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 192/338 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs387907208, CM124860, COSV53963892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 98/288 reads (34%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 100/243 reads (41%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.3423del p.K1142Rfs*48 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | catalogued as rs746790849; ClinVar: pathogenic; called by mutect2, varscan2
- CARD11 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 135/287 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.432); catalogued as rs577877958, COSV101211076, COSV67802724; called by muse, mutect2, varscan2
- CFTR | c.3472C>T p.R1158* | Nonsense Mutation (SNP) | VAF 48/154 reads (31%) | catalogued as rs79850223, CM920180, COSV50107726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 61/235 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 197/457 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 434/801 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.5476C>T p.R1826* | Nonsense Mutation (SNP) | VAF 100/241 reads (41%) | catalogued as rs747349942, CM983961, COSV70356540; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LARS2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 146/382 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs770440975, COSV55530962; ClinVar: likely pathogenic; called by muse, varscan2
- MLH1 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 298/378 reads (79%) | catalogued as rs63749795, CM000177, COSV51615892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MUTYH | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143353451, CM042753, COSV58344345; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NR2E3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs527236086, CM1312695, COSV100489160, COSV58907132; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 60/136 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs786201057, CM102351, CM157948, COSV52667346, COSV52673504, COSV52688693, COSV99037266; ClinVar: likely pathogenic / pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TRPS1 | c.2686dup p.C896Lfs*42 (on ENST00000220888 / NM_001330599.2; = p.C909Lfs*42 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 44/250 reads (18%) | catalogued as rs1554617582; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- VWF | c.6553C>T p.R2185W | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569962285, COSV99777509; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ZBTB18 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as rs1064792999, CM162492, COSV62396102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs200966429, COSV99907600; called by muse, mutect2, varscan2
- AADACL4 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.094); catalogued as rs775507000, COSV66105905; called by muse, mutect2, varscan2
- ABCA1 | c.3187G>A p.V1063M | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101036278; called by muse, mutect2, varscan2
- ABCA9 | c.4130T>C p.L1377P | Missense Mutation (SNP) | VAF 127/415 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs137862082; called by muse, mutect2, varscan2
- ABCC6 | c.3956C>T p.A1319V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as rs1326218777, COSV99227808; called by muse, mutect2, varscan2
- ABCC6 | c.1250T>C p.V417A | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.509); catalogued as COSV99227812; called by muse, mutect2, varscan2
- ABCC9 | c.2199-1G>A p.X733_splice | Splice Site (SNP) | VAF 52/254 reads (20%) | catalogued as COSV99683828; called by muse, mutect2, varscan2
- ABHD5 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 273/684 reads (40%) | catalogued as COSV99185452; called by muse, mutect2, varscan2
- ABI3BP | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 315/841 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs377450718; called by muse, mutect2, varscan2
- AC092143.1 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59248807; called by muse, mutect2, varscan2
- ACADVL | c.388_390del p.E130del | In Frame Del (DEL) | VAF 17/70 reads (24%) | catalogued as rs387906251; called by pindel, varscan2
- ACSM5 | c.624-1G>T p.X208_splice | Splice Site (SNP) | VAF 57/165 reads (35%) | catalogued as COSV100088188, COSV100089757; called by muse, mutect2, varscan2
- ACTN1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs765149759, COSV99516943; called by muse, mutect2, varscan2
- ADAMTS14 | c.3026G>T p.R1009M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100941202; called by muse, mutect2, varscan2
- ADAMTS14 | c.3478C>A p.P1160T | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV64601013; called by muse, mutect2, varscan2
- ADAMTS18 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 86/235 reads (37%) | catalogued as COSV99270713; called by muse, mutect2, varscan2
- ADAMTS2 | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 210/474 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761111411, COSV52397039, COSV99283778; called by muse, mutect2, varscan2
- ADCY1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 213/522 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as COSV52030015, COSV99810988; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.100T>C p.C34R | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100416045; called by muse, mutect2, varscan2
- ADD2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV100034287; called by muse, mutect2, varscan2
- ADGRA3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.658); catalogued as COSV99292722; called by muse, varscan2
- ADGRB3 | c.1276C>A p.Q426K | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100999332; called by muse, mutect2, varscan2
- ADGRG6 | c.1217G>T p.R406M | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51600896, COSV51601845; called by muse, mutect2, varscan2
- ADRB1 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100992238; called by muse, mutect2, varscan2
- AFF1 | c.2406G>T p.R802S | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV57122430, COSV57123197; called by muse, mutect2, varscan2
- AFMID | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs771105807, COSV59975387; called by muse, mutect2, varscan2
- AGAP2 | c.3028G>A p.V1010M (on ENST00000547588 / NM_001122772.2; = p.V654M on NM_014770.4) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV99221858; called by muse, mutect2, varscan2
- AGMAT | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs199886325, COSV65435821; called by muse, mutect2, varscan2
- AGPAT4 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100210698; called by muse, varscan2
- AHCYL1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 82/210 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754117077, COSV100779280; called by muse, mutect2, varscan2
- AHI1 | c.3223G>A p.G1075R | Missense Mutation (SNP) | VAF 188/467 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs750115460, COSV99661636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK2 | c.16544C>T p.S5515L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs757019628, COSV60927512; called by muse, mutect2, varscan2
- AHR | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 114/261 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54121955; called by muse, mutect2, varscan2
- AK8 | c.36del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs757477831; called by mutect2, pindel, varscan2
- AKAP6 | c.2806C>T p.Q936* | Nonsense Mutation (SNP) | VAF 224/565 reads (40%) | catalogued as COSV99797087; called by muse, mutect2, varscan2
- AKAP9 | c.6976A>G p.T2326A (on ENST00000359028; = p.T2302A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100661730; called by muse, mutect2, varscan2
- AL592490.1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV69427556; called by muse, mutect2, varscan2
- ALAD | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201127458, COSV52958654; called by muse, mutect2, varscan2
- ALAS1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867595113, COSV59629106; called by muse, mutect2, varscan2
- ALDH1B1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs201118307, COSV100890871; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel
- ALDH7A1 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752533662, COSV101301971; called by muse, mutect2, varscan2
- ALPK2 | c.4327C>A p.H1443N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV100863856; called by muse, mutect2, varscan2
- AMHR2 | c.800del p.G267Vfs*25 | Frame Shift Del (DEL) | VAF 29/114 reads (25%) | catalogued as rs748387033; called by mutect2, pindel, varscan2
- AMPH | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 307/757 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs151055033; called by muse, mutect2, varscan2
- ANGEL2 | c.364T>C p.S122P | Missense Mutation (SNP) | VAF 123/283 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100853896; called by muse, mutect2, varscan2
- ANK2 | c.5413C>T p.P1805S | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99998633; called by muse, mutect2, varscan2
- ANKMY2 | c.654G>T p.L218F | Missense Mutation (SNP) | VAF 184/442 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV100186748; called by muse, varscan2
- ANKRD30A | c.904del p.T302Hfs*95 (on ENST00000611781; = p.T246Hfs*95 on NM_052997.2) | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs755336380, COSV64619176; called by mutect2, varscan2
- ANKRD50 | c.3521G>A p.R1174Q | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs753523756, COSV72385614; called by muse, mutect2, varscan2
- ANO1 | c.2349C>T p.I783= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as rs748584110, COSV62449147; called by muse, mutect2, varscan2
- ANTXR1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 294/751 reads (39%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.998); catalogued as rs778487700, COSV58010465, COSV58020941; called by muse, mutect2, varscan2
- AP002748.5 | c.1590G>T p.Q530H | Missense Mutation (SNP) | VAF 274/570 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV100567582; called by muse, mutect2, varscan2
- APOB | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 166/429 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV99262659; called by muse, varscan2
- APOC1 | c.129_130del p.L44Gfs*15 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | catalogued as rs756665290; called by pindel, varscan2
- APP | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 34/650 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs200487832, COSV61001845; called by muse, mutect2
- AQP2 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs781478659, CM972978, COSV52229898; called by muse, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | catalogued as rs759782104; called by mutect2, pindel, varscan2
- ARAP3 | c.4292G>T p.W1431L | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.007); catalogued as COSV99499151; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs773922861; called by mutect2, varscan2
- ARHGAP32 | c.4597C>T p.R1533C (on ENST00000310343 / NM_001378025.1; = p.R1184C on NM_014715.4) | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs142674734; called by muse, varscan2
- ARHGAP9 | c.1235A>C p.E412A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99953499; called by muse, mutect2, varscan2
- ARHGEF2 | c.1798A>T p.K600* (on ENST00000361247 / NM_001162383.2; = p.K572* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100559825; called by muse, mutect2
- ARHGEF2 | c.1797G>T p.Q599H (on ENST00000361247 / NM_001162383.2; = p.Q571H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100559827; called by muse, mutect2
- ARID5B | c.2939A>G p.H980R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.006); catalogued as rs759982287, COSV99688704; called by muse, mutect2, varscan2
- ASH1L | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 288/790 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs1416735817, COSV64207287; called by muse, mutect2, varscan2
- ASL | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs796051931, COSV100508752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPM | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 164/440 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as rs1227283442, COSV99659125; called by muse, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 74/201 reads (37%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATAD3B | c.593G>A p.S198N (on ENST00000308647; = p.S304N on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV100426227; called by muse, mutect2, varscan2
- ATG2A | c.1363T>C p.F455L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101033658; called by muse, mutect2, varscan2
- ATG9A | c.1441C>A p.L481M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs190418139, COSV99521330; called by muse, mutect2, varscan2
- ATP2A2 | c.3077T>C p.V1026A | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100428272; called by muse, mutect2
- ATP4A | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52868670; called by muse, mutect2, varscan2
- ATP5F1A | c.917A>G p.H306R | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99958662; called by muse, mutect2, varscan2
- ATP8B4 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 114/338 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as COSV99462645; called by muse, mutect2, varscan2
- ATXN1 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.999); catalogued as rs757447543, COSV55208512; called by muse, mutect2, varscan2
- AVL9 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 163/400 reads (41%) | catalogued as rs149731136; called by muse, mutect2, varscan2
- B4GALNT1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 125/243 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs765536804, COSV57542116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BACH2 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 149/386 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57591356, COSV57611564; called by muse, mutect2, varscan2
- BAHD1 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV101346700; called by muse, mutect2
- BCAM | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99538393; called by muse, mutect2
- BCAR3 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV99549951; called by muse, mutect2, varscan2
- BCKDK | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.666); catalogued as COSV54891517; called by muse, mutect2, varscan2
- BCL6 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.165); catalogued as rs767642014, COSV51655892; called by muse, mutect2, varscan2
- BCL9L | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.451); catalogued as rs762366458, COSV100599349; called by muse, mutect2, varscan2
- BCR | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410579779, COSV100005713; called by muse, mutect2, varscan2
- BGN | c.377T>A p.I126N | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100525041; called by muse, mutect2, varscan2
- BIRC3 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as rs759842920, COSV99679557; called by muse, varscan2
- BIRC3 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs200008391, COSV54816536; called by muse, varscan2
- BIRC6 | c.7420C>A p.L2474M | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.956); catalogued as COSV70204454; called by muse, mutect2
- BLCAP | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99289914; called by muse, mutect2, varscan2
- BMP7 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1247818896, COSV101215231; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 26/62 reads (42%) | catalogued as rs749043197; called by mutect2, varscan2
- BRINP2 | c.13T>A p.C5S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV100837768; called by muse, mutect2, varscan2
- BTBD1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99915098; called by muse, mutect2, varscan2
- BTBD10 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 135/361 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs767910760, COSV53398407; called by muse, mutect2, varscan2
- BTBD16 | c.1210T>C p.F404L | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99584381; called by muse, mutect2, varscan2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 32/276 reads (12%) | catalogued as rs757227190; called by mutect2, varscan2
- C11orf49 | c.217del p.H73Tfs*24 | Frame Shift Del (DEL) | VAF 138/409 reads (34%) | catalogued as rs780813798; called by mutect2, pindel, varscan2
- C17orf64 | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99293249; called by muse, mutect2, varscan2
- C17orf97 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as rs373476599; called by muse, varscan2
- C19orf44 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as rs1235224151, COSV99684821; called by muse, mutect2, varscan2
- C1S | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 171/627 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as rs782476821, COSV100196247; called by muse, mutect2, varscan2
- C21orf91 | c.597dup p.E200Rfs*6 | Frame Shift Ins (INS) | VAF 61/126 reads (48%) | catalogued as rs1307648199; called by mutect2, pindel, varscan2
- C2CD2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs746797812, COSV100297901; called by muse, mutect2, varscan2
- CABIN1 | c.4921C>T p.R1641* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as rs1279300604, COSV99572414; called by muse, mutect2, varscan2
- CACNB4 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1023200310, COSV52390628; called by muse, mutect2, varscan2
- CAD | c.398C>A p.S133Y | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV99254165; called by muse, mutect2, varscan2
- CAMP | c.365del p.G122Afs*65 (on ENST00000296435; = p.G119Afs*65 on NM_004345.5) | Frame Shift Del (DEL) | VAF 131/338 reads (39%) | catalogued as COSV56482061; called by mutect2, pindel, varscan2
- CAND2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as rs530014195, COSV99928312; called by muse, mutect2, varscan2
- CARMIL3 | c.1687A>G p.N563D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100549004; called by muse, mutect2, varscan2
- CAVIN4 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375508129; called by muse, mutect2, varscan2
- CBR4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 144/338 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.129); catalogued as COSV100085724; called by muse, mutect2, varscan2
- CBX2 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99490678; called by muse, mutect2, varscan2
- CBX5 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 128/481 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as COSV52938713; called by muse, mutect2, varscan2
- CC2D2A | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs188018643, COSV67503016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCAR1 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs561113593, COSV99770340; called by muse, mutect2, varscan2
- CCDC106 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs374002589; called by muse, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 40/109 reads (37%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC191 | c.1457G>T p.S486I | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.424); catalogued as COSV99877784; called by muse, mutect2, varscan2
- CCNY | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 144/397 reads (36%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.931); catalogued as rs756155029, COSV99590029; called by muse, varscan2
- CD163L1 | c.3139G>T p.G1047W | Missense Mutation (SNP) | VAF 99/177 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549420; called by muse, mutect2, varscan2
- CD209 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 118/304 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139712001; called by muse, mutect2, varscan2
- CD300E | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 114/268 reads (43%) | catalogued as rs61748965; called by muse, mutect2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 75/319 reads (24%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 45/121 reads (37%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDCA2 | c.2461G>A p.V821I | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100398670; called by muse, mutect2, varscan2
- CDCA7L | c.1215del p.C406Vfs*46 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | catalogued as COSV100181107; called by mutect2, pindel, varscan2
- CDH18 | c.1919A>G p.K640R | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as COSV56953939; called by muse, mutect2, varscan2
- CDH19 | c.343T>G p.L115V | Missense Mutation (SNP) | VAF 111/268 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs768599786, COSV100050537; called by muse, mutect2, varscan2
- CDH2 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 111/296 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV99295035; called by muse, mutect2, varscan2
- CDH4 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs555725508, COSV64669075; called by muse, mutect2, varscan2
- CDH4 | c.1063T>G p.Y355D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848110; called by muse, mutect2, varscan2
- CDHR3 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); catalogued as rs776713785, COSV58420906; called by muse, mutect2, varscan2
- CDK12 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 247/605 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1212731319, COSV101420215; called by muse, mutect2, varscan2
- CEP104 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100986543; called by muse, mutect2, varscan2
- CEP170 | c.619G>C p.A207P | Missense Mutation (SNP) | VAF 147/445 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100316128; called by muse, mutect2, varscan2
- CEP290 | c.5434_5435del p.E1812Kfs*5 | Frame Shift Del (DEL) | VAF 122/611 reads (20%) | catalogued as rs757609119; called by pindel, varscan2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 38/98 reads (39%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CEP97 | c.1855T>A p.F619I | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1560022131, COSV59128381; called by muse, mutect2, varscan2
- CES5A | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs1288510111, COSV99306928; called by muse, mutect2, varscan2
- CETP | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 176/449 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs371258270; ClinVar: benign; called by muse, mutect2, varscan2
- CFAP43 | c.4094T>G p.L1365W | Missense Mutation (SNP) | VAF 149/382 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100828972; called by muse, mutect2, varscan2
- CFAP44 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 172/428 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs113101974, COSV55611403; called by muse, mutect2, varscan2
- CFAP61 | c.2555C>T p.T852M | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV99842361; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 74/234 reads (32%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CGN | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.867); catalogued as COSV54972865; called by muse, mutect2, varscan2
- CHD5 | c.4657G>A p.A1553T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.045); catalogued as rs1160075084, COSV52420130; called by muse, mutect2, varscan2
- CHD5 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770153232, COSV52412970, COSV52414176; called by muse, mutect2, varscan2
- CHDH | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756480475, COSV59460051; called by muse, mutect2, varscan2
- CHKA | c.525G>T p.E175D | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV99693825; called by muse, mutect2, varscan2
- CHRD | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99200215; called by muse, mutect2, varscan2
- CHRNA3 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs76018802, COSV100467603; called by muse, mutect2, varscan2
- CHRNA3 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as rs777301381, COSV58776252; called by muse, mutect2, varscan2
- CIRBP | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV100309625; called by muse, mutect2, varscan2
- CIT | c.4540G>A p.A1514T | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs751322516, COSV55859806, COSV99947919; called by muse, mutect2, varscan2
- CIT | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 224/380 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs781221253, COSV99947921; called by muse, mutect2, varscan2
- CLCN2 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs779315327, COSV99658070; called by muse, mutect2
- CLCN4 | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 123/140 reads (88%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs483352716, COSV66466782; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CLEC3A | c.395C>T p.P132L (on ENST00000651443; = p.P123L on NM_005752.6) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV100221995; called by muse, mutect2, varscan2
- CLEC4F | c.1754G>T p.W585L | Missense Mutation (SNP) | VAF 110/261 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99713420; called by muse, mutect2, varscan2
- CLIC5 | c.1216C>T p.R406C (on ENST00000185206 / NM_001370649.1; = p.R247C on NM_016929.5) | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202022202, COSV51759804; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CLSTN1 | c.1841C>A p.P614H (on ENST00000377298 / NM_001009566.3; = p.P604H on NM_014944.4) | Missense Mutation (SNP) | VAF 199/523 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100790420; called by muse, mutect2, varscan2
- CMIP | c.845G>A p.R282Q (on ENST00000537098 / NM_198390.2; = p.R188Q on NM_030629.3) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.945); catalogued as rs753543941, COSV101220805; called by muse, varscan2
- CNDP2 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs540790918, COSV60841893; called by muse, varscan2
- CNIH2 | c.153C>T p.R51= | Splice Region (SNP) | VAF 10/16 reads (63%) | catalogued as rs374304001; called by muse, mutect2, varscan2
- CNOT10 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100093721; called by muse, varscan2
- COG7 | c.865del p.A289Pfs*54 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs1567340176; called by mutect2, pindel, varscan2
- COL17A1 | c.3778C>T p.R1260C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770168630, COSV100792950; called by muse, mutect2, varscan2
- COL17A1 | c.2839C>A p.L947I | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100792952; called by muse, mutect2, varscan2
- COL4A2 | c.2414del p.P805Lfs*15 | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | catalogued as rs1324194272; called by mutect2, pindel, varscan2
- COL5A2 | c.2137C>T p.R713* | Nonsense Mutation (SNP) | VAF 116/293 reads (40%) | catalogued as COSV100879847; called by muse, mutect2, varscan2
- CPEB3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.48); catalogued as COSV99798057; called by muse, mutect2, varscan2
- CPNE4 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1185355534, COSV70195985; called by muse, mutect2, varscan2
- CPSF1 | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100450086; called by muse, mutect2, varscan2
- CPSF7 | c.232C>T p.R78C (on ENST00000394888 / NM_001136040.4; = p.R121C on NM_024811.4) | Missense Mutation (SNP) | VAF 130/309 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1236908836, COSV100466853; called by muse, mutect2, varscan2
- CPZ | c.1024C>T p.R342C (on ENST00000360986 / NM_001014447.3; = p.R331C on NM_003652.3) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755742622, COSV100248635; called by muse, mutect2, varscan2
- CRADD | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1007288871, COSV60555931; called by muse, mutect2
- CREBBP | c.7030C>T p.R2344W | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1299672210, COSV52121347; called by muse, mutect2, varscan2
- CREBBP | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99062754; called by muse, mutect2, varscan2
- CRY1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV99150255; called by muse, mutect2, varscan2
- CSMD3 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 282/422 reads (67%) | catalogued as COSV99819635; called by muse, varscan2
- CTNND2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs774793947, COSV58874187; called by muse, mutect2, varscan2
- CTPS1 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs552737439, COSV101009247; called by muse, mutect2, varscan2
- CTSF | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs761039140, COSV59748000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL5 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757736723, COSV67610534; called by muse, mutect2, varscan2
- CUL9 | c.6193G>A p.V2065I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs375119455, COSV52728976; called by muse, mutect2, varscan2
- CYLC1 | c.1271del p.K424Rfs*69 | Frame Shift Del (DEL) | VAF 30/44 reads (68%) | catalogued as rs1385226543; called by mutect2, pindel, varscan2
- CYP11B1 | c.1489C>A p.L497I | Missense Mutation (SNP) | VAF 127/949 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); catalogued as COSV99454240; called by muse, mutect2, varscan2
- CYP1A1 | c.739T>C p.S247P | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV101122187; called by muse, mutect2, varscan2
- CYP27C1 | c.1086del p.I364Sfs*14 | Frame Shift Del (DEL) | VAF 60/150 reads (40%) | catalogued as rs767024106; called by mutect2, varscan2
- CYP4F3 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs758905640, COSV99657600; called by muse, mutect2, varscan2
- CYP7B1 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 189/287 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100040356; called by muse, mutect2, varscan2
- DAO | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 163/312 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs566264618, COSV57323592; called by muse, mutect2, varscan2
- DAPK3 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254949642, COSV100009408; called by muse, mutect2, varscan2
- DBNDD1 | c.55C>T p.P19S (on ENST00000002501 / NM_001042610.3; = p.P39S on NM_024043.3) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as COSV99136372; called by muse, mutect2, varscan2
- DCHS1 | c.8173G>A p.V2725M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1564859204, COSV100197044; called by muse, mutect2, varscan2
- DCLRE1C | c.1057G>A p.E353K (on ENST00000378278 / NM_001350965.2; = p.E238K on NM_022487.4) | Missense Mutation (SNP) | VAF 92/237 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs541855040, COSV100739656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCP2 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV101203830; called by muse, mutect2, varscan2
- DDB1 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57101158; called by muse, mutect2, varscan2
- DDX11 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239984762, COSV99298710; called by muse, mutect2, varscan2
- DDX50 | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV101007156; called by muse, mutect2, varscan2
- DDX55 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 196/656 reads (30%) | catalogued as rs749112253, COSV99434051; called by muse, mutect2, varscan2
- DENND10 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.866); catalogued as rs146864091; called by muse, mutect2, varscan2
- DENND3 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 81/420 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs773734634, COSV52805162, COSV99370069; called by muse, varscan2
- DGKK | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 191/239 reads (80%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.761); catalogued as rs782276961, COSV101052826; called by muse, mutect2, varscan2
- DGKZ | c.1246G>A p.E416K (on ENST00000454345 / NM_001105540.2; = p.E228K on NM_003646.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs747019540, COSV58995647; called by muse, mutect2, varscan2
- DHX36 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 174/439 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV100273145; called by muse, mutect2, varscan2
- DHX38 | c.1651G>A p.V551M | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs748565651, COSV99194171; called by muse, mutect2, varscan2
- DIS3 | c.2560T>C p.F854L | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV100899816; called by muse, mutect2, varscan2
- DKK4 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs772507402, COSV55182146; called by muse, varscan2
- DLC1 | c.4360G>A p.A1454T (on ENST00000276297 / NM_001348081.2; = p.A1017T on NM_006094.5) | Missense Mutation (SNP) | VAF 125/310 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as rs367679746; called by muse, mutect2, varscan2
- DLD | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs201652869; called by muse, mutect2, varscan2
- DLGAP2 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.389); catalogued as rs775940326, COSV70103218; called by muse, mutect2, varscan2
- DLGAP4 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 113/271 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs900115980, COSV59421170; called by muse, mutect2, varscan2
- DLL1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1313716209, COSV64536606; called by muse, mutect2
- DLL4 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs754788022, COSV99989506; called by muse, mutect2, varscan2
- DMXL2 | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99195896; called by muse, mutect2, varscan2
- DNAH1 | c.6970G>A p.D2324N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs748004643, COSV70231803; called by muse, mutect2, varscan2
- DNAH2 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as rs759660250, COSV99317745; called by muse, mutect2, varscan2
- DNAH5 | c.12586C>A p.Q4196K | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99442784; called by muse, mutect2, varscan2
- DNAH7 | c.7001G>A p.R2334H | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs753046205, COSV100413102, COSV56751660; called by muse, mutect2, varscan2
- DNAJA3 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52160527; called by muse, mutect2, varscan2
- DNAJC11 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV99601686; called by muse, varscan2
- DNER | c.451del p.R151Dfs*23 | Frame Shift Del (DEL) | VAF 33/104 reads (32%) | catalogued as COSV59159503; called by mutect2, pindel, varscan2
- DNMT1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.084); catalogued as rs775139340, COSV100531475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMT3A | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as rs1256370526, COSV53069137, COSV99264918; called by muse, mutect2, varscan2
- DOCK2 | c.4345C>T p.R1449C | Missense Mutation (SNP) | VAF 137/308 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs956858923, COSV99909293; called by muse, mutect2, varscan2
- DOCK6 | c.4054C>T p.R1352C | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs550858597, COSV53912463; called by muse, mutect2, varscan2
- DOLK | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1387612676, COSV58279720; called by muse, mutect2, varscan2
- DPP8 | c.1477C>T p.R493* (on ENST00000341861 / NM_001320875.2; = p.R477* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 47/146 reads (32%) | catalogued as COSV55681982; called by muse, mutect2, varscan2
- DRD5 | c.493T>C p.W165R | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58580173; called by muse, mutect2, varscan2
- DTWD1 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 70/379 reads (18%) | catalogued as COSV99233454; called by muse, mutect2, varscan2
- DUSP1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99495800; called by muse, mutect2, varscan2
- DVL3 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs146812695; called by muse, mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 62/166 reads (37%) | catalogued as rs746509911; called by mutect2, varscan2
- EBLN2 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs376896494; called by muse, mutect2, varscan2
- ECT2L | c.2260-2A>G p.X754_splice | Splice Site (SNP) | VAF 111/236 reads (47%) | catalogued as rs747470215, COSV62886645; called by muse, mutect2, varscan2
- EDAR | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV99302825; called by muse, mutect2, varscan2
- EDC4 | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV54646277, COSV99534122; called by muse, mutect2, varscan2
- EFHD1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 152/347 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.107); catalogued as rs757443440, COSV99081446; called by muse, mutect2, varscan2
- EGR1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53518033; called by muse, mutect2, varscan2
- EGR2 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746273681, COSV99653873; called by muse, mutect2, varscan2
- EHD3 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59031523; called by muse, mutect2, varscan2
- EHMT2 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs144112397; called by muse, mutect2, varscan2
- EIF4G3 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 114/298 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768014443, COSV51691660; called by muse, mutect2, varscan2
- ELL3 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100082410; called by muse, mutect2, varscan2
- EPB41L1 | c.2587G>A p.V863I | Missense Mutation (SNP) | VAF 117/300 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371978327; called by muse, mutect2, varscan2
- EPHA1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs770072024, COSV51970809, COSV51975526; called by muse, mutect2, varscan2
- EPHB4 | c.2215C>T p.R739* | Nonsense Mutation (SNP) | VAF 132/262 reads (50%) | catalogued as rs773967187, COSV100639365; called by muse, mutect2, varscan2
- EPN2 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV100127250; called by muse, mutect2, varscan2
- EPX | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.083); catalogued as rs369339605; called by muse, mutect2, varscan2
- ERBB4 | c.167G>A p.C56Y | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99613896; called by muse, mutect2, varscan2
- ERICH3 | c.2515del p.A839Qfs*21 | Frame Shift Del (DEL) | VAF 125/409 reads (31%) | catalogued as COSV58604339; called by mutect2, pindel, varscan2
- ESF1 | c.512del p.N171Tfs*18 | Frame Shift Del (DEL) | VAF 42/84 reads (50%) | catalogued as rs745713173; called by mutect2, varscan2
- ESRP2 | c.1285C>T p.R429* (on ENST00000565858 / NM_001365264.1; = p.R419* on NM_024939.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99250976; called by muse, mutect2, varscan2
- EXTL3 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 130/307 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); catalogued as rs374083446; called by muse, mutect2, varscan2
- F3 | c.326_328del p.S109del | In Frame Del (DEL) | VAF 36/106 reads (34%) | catalogued as rs1171177725; called by mutect2, pindel, varscan2
- FADS3 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1035734117, COSV99605010; called by muse, mutect2, varscan2
- FAH | c.1084A>G p.M362V | Missense Mutation (SNP) | VAF 149/369 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs371659518; called by muse, mutect2, varscan2
- FAM120B | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750073931, COSV53004837; called by muse, varscan2
- FAM155A | c.1019G>T p.R340M | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101026085; called by muse, mutect2, varscan2
- FAM189A2 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.494); catalogued as COSV99974597; called by muse, mutect2, varscan2
- FAM50B | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs369953711; called by muse, mutect2, varscan2
- FAM71B | c.1453T>C p.Y485H | Missense Mutation (SNP) | VAF 237/566 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100261626; called by muse, mutect2, varscan2
- FAM89B | c.443C>T p.A148V (on ENST00000530349 / NM_001098785.2; = p.A135V on NM_152832.3) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs774914057, COSV100326035; called by muse, mutect2, varscan2
- FAM98C | c.633G>T p.W211C | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99384742; called by muse, mutect2, varscan2
- FANCB | c.883G>T p.G295* | Nonsense Mutation (SNP) | VAF 59/69 reads (86%) | catalogued as COSV100146268; called by muse, mutect2, varscan2
- FAR1 | c.768+2T>C p.X256_splice | Splice Site (SNP) | VAF 53/125 reads (42%) | catalogued as COSV100701477; called by muse, mutect2, varscan2
- FBLN7 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778318785, COSV55616759; called by muse, mutect2, varscan2
- FBN3 | c.3616G>A p.V1206I | Missense Mutation (SNP) | VAF 96/272 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747241812, COSV99559163; called by muse, mutect2, varscan2
- FBXO10 | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs375383268; called by muse, mutect2, varscan2
- FBXO15 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1363832799, COSV54043164; called by muse, mutect2, varscan2
- FBXO43 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs751533209, COSV71055270; called by muse, mutect2, varscan2
- FBXO47 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 188/441 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100960492; called by muse, mutect2, varscan2
- FCGBP | c.8420G>A p.R2807Q | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as rs778200930; called by muse, mutect2, varscan2
- FGF5 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.773); catalogued as rs778270075, COSV100427736; called by muse, mutect2, varscan2
- FGFR2 | c.549del p.N184Tfs*9 | Frame Shift Del (DEL) | VAF 72/207 reads (35%) | catalogued as rs1164513666; called by mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs777980924; called by mutect2, varscan2
- FILIP1 | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1268558002, COSV99383490; called by muse, mutect2, varscan2
- FILIP1L | c.1072dup p.I358Nfs*3 (on ENST00000354552 / NM_182909.3; = p.I118Nfs*3 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 123/424 reads (29%) | catalogued as rs1311581659; called by mutect2, pindel, varscan2
- FIS1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 86/237 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as COSV99778855; called by muse, mutect2, varscan2
- FKBP11 | c.515T>A p.I172N | Missense Mutation (SNP) | VAF 99/309 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99872628; called by muse, mutect2, varscan2
- FKBP14 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321186; called by muse, mutect2, varscan2
- FLNC | c.4541C>T p.T1514M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as rs1159701068, COSV100367410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMNL3 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 144/583 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.059); catalogued as COSV99525394; called by muse, varscan2
- FMO5 | c.263T>G p.V88G | Missense Mutation (SNP) | VAF 130/295 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99566429; called by muse, mutect2, varscan2
- FOXJ2 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 119/202 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs757750422, COSV99367950; called by muse, mutect2, varscan2
- FOXN4 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs759819045, COSV100141966; called by muse, mutect2, varscan2
- FOXO3 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749629630, COSV100669429; called by muse, mutect2, varscan2
- FOXO3 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1322957199, COSV100669434; called by muse, mutect2, varscan2
- FRMD1 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs372041975; called by muse, mutect2, varscan2
- FRMPD4 | c.1857G>T p.E619D | Missense Mutation (SNP) | VAF 52/70 reads (74%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.047); catalogued as COSV101041737; called by muse, mutect2, varscan2
- FRZB | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 125/386 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs924566733, COSV99717197; called by muse, mutect2, varscan2
- FUT9 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs1339153685, COSV56146372; called by muse, mutect2, varscan2
- FUZ | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs773367242, COSV100570933, COSV58240836; called by muse, mutect2, varscan2
- FZD1 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV55312774, COSV99842299; called by muse, mutect2, varscan2
- GABBR2 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 263/610 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755692994, COSV52292416; called by muse, varscan2
- GABBR2 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs778365249, COSV52296116; called by muse, mutect2, varscan2
- GABRB3 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 132/355 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161964, COSV54652552, COSV54658230; called by muse, mutect2, varscan2
- GABRP | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as rs773277344, COSV54662976; called by muse, mutect2, varscan2
- GABRQ | c.1222del p.L408Wfs*10 | Frame Shift Del (DEL) | VAF 66/108 reads (61%) | catalogued as rs1569454161; called by mutect2, pindel, varscan2
- GALNTL6 | c.841G>T p.G281* | Nonsense Mutation (SNP) | VAF 98/207 reads (47%) | catalogued as COSV101559969; called by muse, mutect2, varscan2
- GCNT3 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 64/126 reads (51%) | catalogued as COSV101251698; called by muse, mutect2, varscan2
- GCOM1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 119/358 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs770449271, COSV51088477; called by muse, mutect2, varscan2
- GEMIN2 | c.137del p.P46Rfs*8 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs1566527852; called by mutect2, pindel, varscan2
- GGCX | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs200774203, COSV52089587; called by muse, mutect2, varscan2
- GJA8 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782396294, COSV53788023, COSV99568939; called by muse, mutect2, varscan2
- GK2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 197/536 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.275); catalogued as rs752639242, COSV100725869, COSV62626389; called by muse, mutect2, varscan2
- GLCCI1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 182/546 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777220141, COSV99779982; called by muse, mutect2, varscan2
- GLDC | c.2353G>A p.V785I | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs372101832; called by muse, mutect2, varscan2
- GLIS3 | c.2044C>T p.H682Y | Missense Mutation (SNP) | VAF 113/297 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs751461025, COSV100172813; called by muse, mutect2, varscan2
- GLMN | c.924C>T p.S308= | Splice Region (SNP) | VAF 93/318 reads (29%) | catalogued as rs1371030400, COSV100949902; called by muse, mutect2, varscan2
- GLP2R | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1445249178, COSV99301360; called by muse, mutect2, varscan2
- GLRA2 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 246/310 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54336582; called by muse, varscan2
- GLRX3 | c.475T>C p.C159R | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100487822; called by muse, mutect2, varscan2
- GLYCTK | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769693391, COSV59793374; called by muse, mutect2, varscan2
- GMPR | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs768978971, COSV52472577, COSV99439585; called by muse, mutect2, varscan2
- GOLGA2 | c.2932C>T p.R978W | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs1338016366, COSV57855430; called by mutect2, varscan2
- GPBAR1 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99946083; called by muse, mutect2, varscan2
- GPR39 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs1461565867, COSV61422278; called by muse, mutect2, varscan2
- GPRC5B | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.138); catalogued as rs1442105793, COSV100244345; called by muse, varscan2
- GPX3 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100161006; called by muse, mutect2, varscan2
- GRIA1 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 160/409 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as rs758170711, COSV53620238, COSV99597328; called by muse, mutect2, varscan2
- GRIN3A | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 200/552 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs372945887, COSV100701297; called by muse, mutect2, varscan2
- GRIP2 | c.3140G>A p.R1047Q (on ENST00000619221; = p.R950Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as rs751884082, COSV99816799; called by muse, mutect2, varscan2
- GTF2F1 | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 159/369 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as rs199893553, COSV55532869, COSV99831652; called by muse, mutect2, varscan2
- GTF2IRD1 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs1480640371, COSV56084939; called by muse, mutect2, varscan2
- GUCA1B | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 108/264 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs755162612, COSV99273727; called by muse, mutect2, varscan2
- GUCY2D | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs567708710, COSV99643599; called by muse, mutect2, varscan2
- GUCY2D | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs200637525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GXYLT2 | c.1005G>A p.W335* | Nonsense Mutation (SNP) | VAF 76/298 reads (26%) | catalogued as COSV101274595, COSV101274596; called by muse, mutect2, varscan2
- GZMM | c.43del p.A15Pfs*4 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs1260022730; called by mutect2, varscan2
- HCCS | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs776172899, COSV58238736; called by muse, mutect2
- HCN1 | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 75/144 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV57491706, COSV57502530; called by muse, mutect2, varscan2
- HCN3 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.288); catalogued as rs767894046, COSV61361937; called by muse, mutect2, varscan2
- HCN4 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs998387579, COSV56086816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 62/192 reads (32%) | catalogued as rs755844571, COSV63794110; called by mutect2, pindel
- HDAC9 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 26/261 reads (10%) | catalogued as COSV67781348, COSV67783378; called by muse, mutect2, varscan2
- HDC | c.1245T>C p.G415= | Splice Region (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99983707; called by muse, mutect2, varscan2
- HDLBP | c.1818+2T>C p.X606_splice | Splice Site (SNP) | VAF 56/259 reads (22%) | catalogued as COSV60500063; called by muse, mutect2, varscan2
- HEXIM2 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs760708659, COSV56235817; called by muse, mutect2, varscan2
- HEY2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.806); catalogued as rs769963246, COSV64239865; called by muse, mutect2, varscan2
- HEY2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1280261143, COSV100856247; called by muse, varscan2
- HIVEP2 | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV99171389; called by muse, mutect2, varscan2
- HLA-DQB1 | c.535del p.I180Lfs*12 | Frame Shift Del (DEL) | VAF 19/36 reads (53%) | catalogued as rs751976368; called by mutect2, varscan2
- HNF4A | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1223493898, COSV100290893; called by muse, mutect2
- HNF4A | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.156); catalogued as COSV100290895; called by muse, varscan2
- HOXA6 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs753984515, COSV99762032; called by muse, mutect2, varscan2
- HOXB6 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99494296; called by muse, mutect2, varscan2
- HOXB9 | c.413T>C p.L138S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.26); catalogued as rs200221711, COSV100239410; called by muse, mutect2, varscan2
- HPR | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV99930653; called by muse, mutect2, varscan2
- HS2ST1 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 57/147 reads (39%) | catalogued as rs865888400, COSV63352001; called by muse, mutect2, varscan2
- HTR3E | c.919del p.L307Sfs*12 (on ENST00000415389 / NM_001256613.1; = p.L322Sfs*12 on NM_182589.2) | Frame Shift Del (DEL) | VAF 104/281 reads (37%) | catalogued as rs754509192; called by mutect2, pindel, varscan2
- HVCN1 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 217/738 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.311); catalogued as COSV99656942; called by muse, mutect2, varscan2
- ICAM5 | c.1760T>C p.V587A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as COSV99702999; called by muse, mutect2, varscan2
- IFT140 | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757199524, COSV54152205, COSV54153732; called by muse, mutect2, varscan2
- IFT81 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs765241061, COSV54365872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF1R | c.2066C>T p.T689I | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV99147900; called by muse, mutect2, varscan2
- IGF2R | c.4751T>C p.V1584A | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100806609; called by muse, varscan2
- IGHG4 | c.350del p.G117Dfs*16 | Frame Shift Del (DEL) | VAF 24/119 reads (20%) | catalogued as rs1475796782; called by mutect2, pindel, varscan2
- IGHV3-72 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 192/493 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV101455355; called by muse, mutect2, varscan2
- IGHV5-51 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 228/624 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs782566695; called by muse, mutect2
- IGSF8 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs777061327, COSV58757947; called by muse, mutect2, varscan2
- IKBKB | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV100645534; called by muse, mutect2, varscan2
- IL18BP | c.275T>C p.F92S | Missense Mutation (SNP) | VAF 93/190 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV99474382; called by muse, mutect2, varscan2
- IL21R | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as COSV61972222; called by muse, mutect2, varscan2
- IL27RA | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 197/451 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as rs370071884; called by muse, mutect2, varscan2
- INHBE | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs760258476, COSV99875144; called by muse, mutect2, varscan2
- INPP5D | c.1301C>T p.T434M (on ENST00000445964 / NM_001017915.3; = p.T433M on NM_005541.5) | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1455642398, COSV64039767; called by muse, mutect2, varscan2
- INPPL1 | c.2927dup p.P977Tfs*7 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | catalogued as rs749079348; called by mutect2, varscan2
- INTS5 | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778371875, COSV57952124; called by muse, mutect2, varscan2
- IQSEC2 | c.1208C>A p.P403H (on ENST00000642864 / NM_001111125.3; = p.P198H on NM_015075.2) | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV100944657; called by muse, mutect2, varscan2
- IRF3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1456700189, COSV55863507; called by muse, mutect2, varscan2
- IRS1 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs942813013, COSV59335233; called by muse, mutect2
- ISLR2 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as rs777224671, COSV62303447; called by muse, mutect2, varscan2
- ITFG1 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs758393141, COSV57748092; called by mutect2, varscan2
- ITGA2B | c.1496C>A p.P499H | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99288392; called by muse, mutect2, varscan2
- ITGBL1 | c.1325A>T p.Y442F | Missense Mutation (SNP) | VAF 791/1795 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.265); catalogued as COSV66004898; called by muse, mutect2, varscan2
- ITIH1 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs775722288, COSV99834792; called by muse, mutect2, varscan2
- ITIH3 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs199816198, COSV101406879; called by muse, mutect2, varscan2
- ITPR3 | c.6784C>T p.R2262C | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1438477715, COSV100966725; called by muse, mutect2, varscan2
- IZUMO1 | c.344T>C p.L115S | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99710375; called by muse, mutect2
- JAK1 | c.1016del p.N339Ifs*3 | Frame Shift Del (DEL) | VAF 174/534 reads (33%) | catalogued as rs1181132297; called by mutect2, pindel, varscan2
- JAKMIP3 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754433822, COSV100058422; called by muse, mutect2, varscan2
- JAKMIP3 | c.765G>T p.E255D | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV100058423; called by muse, mutect2, varscan2
- JHY | c.935T>A p.I312N | Missense Mutation (SNP) | VAF 148/399 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV57080252; called by muse, mutect2
- KAT6A | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs372273756; called by muse, mutect2, varscan2
- KCND1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs782488264, COSV99501586; called by muse, mutect2, varscan2
- KCNE4 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV56055195; called by muse, varscan2
- KCNV2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1449828854, COSV101172437; called by muse, mutect2, varscan2
- KCTD19 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 51/122 reads (42%) | catalogued as rs776633709, COSV100430571; called by muse, mutect2, varscan2
- KDR | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 111/260 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as rs199982402, COSV55771246; called by muse, mutect2, varscan2
- KIAA0753 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 189/515 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.319); catalogued as rs370311617; called by muse, mutect2, varscan2
- KIF16B | c.3569G>A p.R1190H | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1345910626, COSV61704500; called by muse, mutect2, varscan2
- KIF23 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs756964640, COSV52980273; called by muse, mutect2, varscan2
- KIF26B | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769468332, COSV100833514, COSV63636821; called by muse, mutect2, varscan2
- KLF15 | c.1142A>G p.Y381C | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99955007; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 47/94 reads (50%) | catalogued as rs749194179; called by mutect2, pindel
- KLHL5 | c.1433C>T p.T478I | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.516); catalogued as COSV54679536, COSV99784591; called by muse, mutect2, varscan2
- KLRB1 | c.58A>T p.S20C | Missense Mutation (SNP) | VAF 58/856 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99987129; called by muse, mutect2
- KMT2B | c.3509G>A p.R1170H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1313553140, COSV99718516; called by muse, mutect2, varscan2
- KRT38 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs767626446, COSV55846793; called by muse, mutect2, varscan2
- KRT74 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 87/154 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs775208348, COSV99977331; called by muse, mutect2, varscan2
- LAMB4 | c.673A>G p.N225D | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99222155; called by muse, mutect2, varscan2
- LAT | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756908098, COSV100208756; called by muse, mutect2, varscan2
- LAYN | c.700G>A p.A234T (on ENST00000375615 / NM_001258390.1; = p.A226T on NM_178834.5) | Missense Mutation (SNP) | VAF 256/708 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV100986122; called by muse, varscan2
- LCT | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1340454714, COSV51543851; called by muse, mutect2, varscan2
- LDB1 | c.756G>A p.M252I (on ENST00000425280 / NM_001321612.2; = p.M216I on NM_003893.5) | Missense Mutation (SNP) | VAF 99/245 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100756287; called by muse, mutect2, varscan2
- LDLRAD3 | c.103T>C p.F35L | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100214117; called by muse, mutect2, varscan2
- LHX8 | c.1051C>A p.L351M | Missense Mutation (SNP) | VAF 176/418 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99632703; called by muse, mutect2, varscan2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | catalogued as rs748571616; called by mutect2, varscan2
- LOXL2 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs772042943, COSV66690339; called by muse, mutect2, varscan2
- LPAR3 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as rs751975084, COSV65454820; called by muse, mutect2, varscan2
- LPIN3 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs765565818, COSV100952809; called by muse, mutect2, varscan2
- LRIT1 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs1330461774, COSV100927963; called by muse, mutect2, varscan2
- LRRC28 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 152/377 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs761561702, COSV100113183; called by muse, mutect2, varscan2
- LRRC37B | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs754480928, COSV100495890; called by muse, mutect2, varscan2
- LRRC41 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1438184499, COSV58441819; called by muse, mutect2, varscan2
- LRRC4C | c.1753C>A p.L585M | Missense Mutation (SNP) | VAF 287/700 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.104); catalogued as rs1268402542, COSV99536378; called by muse, mutect2, varscan2
- LRRC59 | c.803T>A p.V268E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV99869263; called by muse, mutect2, varscan2
- LRRC8A | c.2270C>T p.T757M | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs557710052, COSV99396123; called by muse, mutect2, varscan2
- LRRK1 | c.4490C>T p.A1497V | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs767617347, COSV99436759; called by muse, mutect2, varscan2
- LRRK2 | c.4648C>T p.R1550W | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1555188401, COSV100108498; called by muse, mutect2, varscan2
- MAGI1 | c.3857C>T p.S1286L | Missense Mutation (SNP) | VAF 151/429 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58312409; called by muse, mutect2, varscan2
- MAGI2 | c.3424-2A>G p.X1142_splice | Splice Site (SNP) | VAF 113/268 reads (42%) | catalogued as COSV100831576; called by muse, mutect2, varscan2
- MAP2K2 | c.311A>G p.H104R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV53569164; called by muse, mutect2, varscan2
- MAP3K21 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 237/500 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759521299, COSV100786190; called by muse, mutect2, varscan2
- MAP3K21 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100786191; called by muse, mutect2, varscan2
- MAP3K4 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62334571; called by muse, mutect2, varscan2
- MAP7D3 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 74/96 reads (77%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs749992584, COSV60172939; called by muse, mutect2, varscan2
- MAPK8 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 121/295 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs773780784, COSV64410081; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99167578; called by muse, mutect2, varscan2
- MARK1 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 91/229 reads (40%) | catalogued as rs1346347772, COSV65068250; called by muse, mutect2, varscan2
- MAST1 | c.2948C>T p.A983V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52249519, COSV99261970; called by muse, mutect2, varscan2
- MATN2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs377009254; called by muse, mutect2, varscan2
- MB21D2 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV101164866; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs749738168; called by mutect2, varscan2
- MCF2L2 | c.1858del p.R620Afs*16 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as COSV100193332; called by mutect2, pindel
- MCF2L2 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 73/160 reads (46%) | catalogued as rs1450813503, COSV61053896; called by muse, mutect2, varscan2
- MED13 | c.4844G>T p.S1615I | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101180675; called by muse, mutect2, varscan2
- MED13 | c.2531T>C p.I844T | Missense Mutation (SNP) | VAF 122/277 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV101180676; called by muse, mutect2, varscan2
- MED24 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100672738; called by muse, mutect2
- MEGF6 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373558942; called by mutect2, varscan2
- MEGF8 | c.1668C>T p.D556= | Splice Region (SNP) | VAF 34/79 reads (43%) | catalogued as rs370015031; called by muse, mutect2, varscan2
- METTL16 | c.962T>C p.M321T | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV99562918; called by muse, mutect2, varscan2
- METTL16 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as rs768657565, COSV99562920; called by muse, mutect2, varscan2
- MFSD8 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99614044; called by muse, mutect2, varscan2
- MIEF1 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.265); catalogued as rs143931307; called by muse, mutect2, varscan2
- MITF | c.1517G>A p.R506Q (on ENST00000448226 / NM_006722.3; = p.R406Q on NM_000248.4) | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1018390529, COSV58833050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MKI67 | c.5717C>T p.T1906M | Missense Mutation (SNP) | VAF 246/561 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs776996722, COSV100895967; called by muse, mutect2, varscan2
- MLF2 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs773985602, COSV99180046; called by muse, varscan2
- MLIP | c.1113+1G>T p.X371_splice | Splice Site (SNP) | VAF 47/128 reads (37%) | catalogued as COSV99228055; called by muse, mutect2, varscan2
- MMP16 | c.132+2T>C p.X44_splice | Splice Site (SNP) | VAF 125/196 reads (64%) | catalogued as COSV99685241; called by muse, mutect2, varscan2
- MMP7 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs145006821; called by muse, mutect2, varscan2
- MMP9 | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100812297; called by muse, mutect2, varscan2
- MMP9 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751218589, COSV100812298; called by muse, mutect2, varscan2
- MNDA | c.42T>G p.F14L | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100933214; called by muse, mutect2, varscan2
- MNT | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99437854; called by muse, mutect2, varscan2
- MON2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 188/347 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1180236114, COSV99741210; called by muse, mutect2, varscan2
- MROH1 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1053634097; called by muse, mutect2, varscan2
- MRPL37 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 88/217 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs753105572, COSV100288959; called by muse, mutect2, varscan2
- MSN | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs757131925, COSV100814024; called by muse, mutect2, varscan2
- MTMR10 | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100075667; called by muse, mutect2, varscan2
- MTRES1 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 55/132 reads (42%) | catalogued as rs1554227380, COSV100261072; called by muse, mutect2, varscan2
- MTTP | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 97/217 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99644528; called by muse, mutect2, varscan2
- MUC16 | c.30625del p.T10209Hfs*19 | Frame Shift Del (DEL) | VAF 122/330 reads (37%) | catalogued as COSV67487448; called by mutect2, pindel, varscan2
- MUSK | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 224/592 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs774463260, COSV99503417; called by muse, mutect2, varscan2
- MXRA5 | c.6568G>A p.A2190T | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.558); catalogued as COSV54249775; called by muse, mutect2, varscan2
- MXRA5 | c.6182C>T p.P2061L | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.98); PolyPhen benign (0.39); catalogued as rs200199741, COSV99475235; called by muse, mutect2, varscan2
- MXRA5 | c.2305C>T p.R769* | Nonsense Mutation (SNP) | VAF 239/282 reads (85%) | catalogued as COSV99475236; called by muse, varscan2
- MXRA7 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 50/144 reads (35%) | PolyPhen probably damaging (0.999); catalogued as rs1038906917, COSV63321189; called by muse, mutect2, varscan2
- MYBL1 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 519/841 reads (62%) | catalogued as COSV101576438; called by muse, mutect2, varscan2
- MYBPC3 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs373638535, CM138715, COSV99908560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYBPH | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146696842; called by muse, mutect2, varscan2
- MYF5 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57356615; called by muse, mutect2, varscan2
- MYH6 | c.5095C>T p.R1699W | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766345714, COSV100676109; called by muse, mutect2, varscan2
- MYH7 | c.4606G>A p.E1536K | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs779315151, CM115873, COSV62516010; called by muse, mutect2, varscan2
- MYL9 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs775610439, COSV99640899; called by muse, mutect2, varscan2
- MYO10 | c.4306G>A p.A1436T | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as rs753505470, COSV99944382; called by muse, mutect2, varscan2
- MYO10 | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 95/372 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV101569722; called by muse, mutect2, varscan2
- MYO1B | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100268304; called by muse, mutect2, varscan2
- MYO7A | c.4921G>A p.E1641K | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); catalogued as rs767975012, CM1310726, COSV101288995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 172/424 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs375889597; called by muse, mutect2, varscan2
- MYOZ1 | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 139/287 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831739; called by muse, mutect2, varscan2
- MYOZ3 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99770520; called by muse, mutect2, varscan2
- MYRIP | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 138/290 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769986510, COSV100218023; called by muse, mutect2, varscan2
- MYT1L | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs1263025144, COSV101217690; called by muse, mutect2, varscan2
- NADK | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs750455546, COSV100410514; called by muse, mutect2, varscan2
- NARS2 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55252549; called by muse, mutect2, varscan2
- NARS2 | c.737A>T p.N246I | Missense Mutation (SNP) | VAF 156/368 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55249556, COSV99806816; called by muse, mutect2, varscan2
- NAXD | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs752108793, COSV57288631; called by muse, mutect2, varscan2
- NBEAL2 | c.4582C>T p.R1528C | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52759404; called by muse, mutect2, varscan2
- NCBP1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV100912501; called by muse, mutect2, varscan2
- NCL | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.557); catalogued as COSV100502151; called by muse, mutect2, varscan2
- NCOA2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 169/686 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as rs1217727548, COSV71763398; called by muse, mutect2, varscan2
- NCOA5 | c.1010del p.G337Afs*38 | Frame Shift Del (DEL) | VAF 62/206 reads (30%) | catalogued as rs1200193975; called by mutect2, pindel, varscan2
- NEBL | c.1381G>T p.G461* | Nonsense Mutation (SNP) | VAF 194/534 reads (36%) | catalogued as COSV65801666; called by muse, mutect2, varscan2
- NECTIN1 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as rs148045547; called by muse, mutect2
- NECTIN2 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 173/445 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV99374698; called by muse, mutect2, varscan2
- NEDD4L | c.2674G>A p.A892T (on ENST00000400345 / NM_001144967.3; = p.A872T on NM_015277.6) | Missense Mutation (SNP) | VAF 142/325 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV99892932; called by muse, mutect2, varscan2
- NEK8 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as rs771755365, COSV52047719; called by muse, mutect2, varscan2
- NELFA | c.716C>T p.A239V (on ENST00000542778; = p.A228V on NM_005663.5) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs1237156456, COSV100372678; called by muse, mutect2, varscan2
- NEUROD1 | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99716725; called by muse, mutect2, varscan2
- NEXMIF | c.4321G>A p.G1441R | Missense Mutation (SNP) | VAF 314/396 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs745720102, COSV50034642; called by muse, mutect2, varscan2
- NFIB | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66620392; called by muse, mutect2, varscan2
- NICN1 | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV56469044, COSV56471088; called by muse, mutect2, varscan2
- NLE1 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs750583113, COSV50101998; called by muse, mutect2, varscan2
- NLGN2 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.323); catalogued as rs924724424, COSV57212435; called by muse, mutect2, varscan2
- NMUR2 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1053157647, COSV54917078, COSV54917864; called by muse, varscan2
- NOS1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs1219636809, COSV57613651; called by muse, mutect2, varscan2
- NOS1 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 198/621 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1451276089, COSV57610696; called by muse, mutect2, varscan2
- NPAS4 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV100214676; called by muse, mutect2, varscan2
- NQO2 | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 142/343 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100583093; called by muse, mutect2, varscan2
- NRXN1 | c.2566C>T p.R856W | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796052777, COSV58442242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 41/115 reads (36%) | catalogued as COSV55073962; called by mutect2, varscan2
- NTN4 | c.1628A>G p.E543G | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100643608; called by muse, mutect2, varscan2
- NUB1 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV100879188; called by muse, mutect2, varscan2
- ODC1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as COSV52172852; called by muse, mutect2, varscan2
- OMD | c.1142G>T p.R381M | Missense Mutation (SNP) | VAF 306/752 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100978998; called by muse, mutect2, varscan2
- OMP | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV99581536; called by muse, mutect2, varscan2
- OR10P1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs752296913, COSV100548082; called by muse, mutect2, varscan2
- OR2A7 | c.532del p.C178Vfs*37 | Frame Shift Del (DEL) | VAF 32/318 reads (10%) | catalogued as rs749245232; called by pindel, varscan2
- OR2L13 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV63555839; called by muse, mutect2, varscan2
- OR2T27 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs543746159, COSV61281246, COSV61283337; called by muse, mutect2, varscan2
- OR51S1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs776320504, COSV100437302; called by muse, varscan2
- OR5M10 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.595); catalogued as rs566095437, COSV73242337; called by muse, mutect2, varscan2
- OR6Q1 | c.830T>A p.V277E | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100108974; called by muse, mutect2, varscan2
- OR7A17 | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 167/388 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100541532; called by muse, mutect2, varscan2
- OTOA | c.1961T>C p.V654A (on ENST00000286149; = p.V640A on NM_144672.4) | Missense Mutation (SNP) | VAF 136/339 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV99623211; called by muse, mutect2, varscan2
- OTUD4 | c.254G>C p.G85A (on ENST00000447906 / NM_001366057.1; = p.G20A on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56851155, COSV99668975; called by muse, mutect2, varscan2
- P2RY1 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.226); catalogued as COSV100521592; called by muse, mutect2, varscan2
- P2RY12 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764657007, COSV99850811; called by muse, mutect2, varscan2
- PABPC1L | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs199499305; called by muse, mutect2, varscan2
- PACSIN1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV99762796; called by muse, mutect2, varscan2
- PADI6 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs529584194, COSV100639873; called by muse, mutect2, varscan2
- PADI6 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs754193133, COSV100639874; called by muse, mutect2, varscan2
- PAFAH1B3 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as rs771659012, COSV50647904; called by muse, mutect2, varscan2
- PAK5 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 226/537 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs991533102, COSV62023211; called by muse, mutect2, varscan2
- PAN3 | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 108/258 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as COSV99144478; called by muse, mutect2, varscan2
- PAPOLG | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 100/258 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.044); catalogued as rs749124361, COSV53181497; called by muse, mutect2, varscan2
- PAPPA | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 98/207 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1457198734, COSV100072492; called by muse, mutect2, varscan2
- PARD6A | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV99537263; called by muse, mutect2, varscan2
- PAX3 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD920899, CM102004, COSV99286285; called by muse, mutect2, varscan2
- PAX6 | c.357C>T p.S119= | Splice Region (SNP) | VAF 12/35 reads (34%) | catalogued as rs121907928, CD082176, CM013024, CM993965, COSV53794419, COSV99570036; called by muse, mutect2, varscan2
- PC | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs916937580, COSV100546909; called by muse, mutect2, varscan2
- PC | c.1571C>A p.P524H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100540570; called by muse, mutect2, varscan2
- PCDH9 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); catalogued as rs753210691, COSV60527839, COSV60592737; called by muse, mutect2
- PCDHA2 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as rs143944331, COSV65365419; called by muse, mutect2, varscan2
- PCDHA3 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.877); catalogued as rs1290587407, COSV100793021; called by muse, mutect2, varscan2
- PCDHA5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1393571238, COSV65349067; called by muse, mutect2, varscan2
- PCED1B | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as COSV101423581; called by muse, mutect2, varscan2
- PCSK5 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.489); catalogued as rs1277845846, COSV65094016; called by muse, varscan2
- PDGFRB | c.113del p.P38Rfs*15 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as COSV55800592; called by pindel, varscan2
- PDPR | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753917254, COSV99847536; called by muse, mutect2, varscan2
- PDZD2 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556048029, COSV56853343; called by muse, mutect2, varscan2
- PDZD2 | c.2900C>T p.A967V | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV56870927; called by muse, mutect2, varscan2
- PDZD7 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 85/219 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100931525; called by muse, mutect2, varscan2
- PEAR1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150236151, COSV52772369; called by muse, mutect2, varscan2
- PGAM5 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100452882; called by muse, mutect2, varscan2
- PGAP2 | c.220C>T p.R74C (on ENST00000463452 / NM_001346398.2; = p.R135C on NM_014489.4) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV53464819; called by muse, varscan2
- PGBD1 | c.2005del p.M669* | Frame Shift Del (DEL) | VAF 59/171 reads (35%) | catalogued as rs781166611; called by mutect2, pindel, varscan2
- PGBD4 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.622); catalogued as rs1298038398, COSV99854651; called by muse, mutect2, varscan2
- PGC | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs531970409, COSV100756795; called by muse, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs761575760; called by mutect2, pindel, varscan2
- PHLPP2 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 121/318 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs372879648, COSV62426387, COSV62427462; called by muse, varscan2
- PHOX2B | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs1192207345, COSV56931547; called by muse, mutect2, varscan2
- PHYHIP | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs771602736, COSV58689031; called by muse, mutect2, varscan2
- PIGR | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs529407537, COSV62903193; called by muse, varscan2
- PIK3CA | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55980465; called by muse, mutect2, varscan2
- PIK3CD | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as rs143116020; called by muse, mutect2, varscan2
- PINX1 | c.474C>T p.G158= | Splice Region (SNP) | VAF 41/159 reads (26%) | catalogued as rs762236736, COSV59108431; called by muse, mutect2, varscan2
- PIWIL2 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs772112294, COSV100769106; called by muse, mutect2, varscan2
- PKNOX2 | c.144del p.S49Qfs*35 | Frame Shift Del (DEL) | VAF 35/87 reads (40%) | catalogued as rs1565508191; called by mutect2, pindel, varscan2
- PKP2 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 224/772 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs753912985, COSV50732952, COSV99296981; called by muse, mutect2, varscan2
- PLAAT1 | c.520C>T p.Q174* (on ENST00000650797; = p.Q69* on NM_020386.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 120/344 reads (35%) | catalogued as COSV99290458; called by muse, mutect2, varscan2
- PLEKHG3 | c.1790G>A p.R597Q (on ENST00000394691; = p.R653Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs377488568; called by muse, mutect2, varscan2
- PLEKHG4B | c.1205T>G p.L402R (on ENST00000283426; = p.L758R on NM_052909.5) | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99359530; called by muse, mutect2, varscan2
- PLEKHO1 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); catalogued as rs782519422, COSV99215024; called by muse, mutect2, varscan2
- PLK1 | c.1078_1080del p.E360del | In Frame Del (DEL) | VAF 20/96 reads (21%) | catalogued as rs1230691153; called by pindel, varscan2
- PLXNB1 | c.1468T>C p.S490P | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99601953; called by muse, mutect2, varscan2
- PLXND1 | c.4678G>A p.V1560M | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762249042, COSV100138794; called by muse, mutect2, varscan2
- PMM1 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190292776, COSV99347973; called by muse, mutect2, varscan2
- PNKP | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99681482; called by muse, mutect2, varscan2
- POGLUT3 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.281); catalogued as rs750568803, COSV100052429; called by muse, mutect2, varscan2
- POLB | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV55346826; called by muse, mutect2, varscan2
- POLM | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1396168979, COSV54242546; called by muse, mutect2, varscan2
- POLR1A | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs780248678, COSV55691549, COSV55694876; called by muse, mutect2, varscan2
- POLR3C | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV61937118; called by muse, mutect2, varscan2
- POLR3E | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs749348251, COSV100241782; called by muse, mutect2, varscan2
- POM121C | c.2707G>A p.A903T (on ENST00000607367; = p.A661T on NM_001099415.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782333810; called by mutect2, varscan2
- POU5F2 | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV101232626; called by muse, varscan2
- PPP2R2D | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV70778911; called by muse, mutect2, varscan2
- PPP4R3B | c.787del p.I263Yfs*40 | Frame Shift Del (DEL) | VAF 61/177 reads (34%) | catalogued as rs1198364136; called by mutect2, pindel, varscan2
- PREX1 | c.4961C>T p.P1654L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1000110812, COSV100905970, COSV99057784; called by muse, mutect2, varscan2
- PRICKLE3 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs781985242, COSV66235061; called by muse, mutect2, varscan2
- PRKACG | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs138280963; called by muse, mutect2, varscan2
- PRKDC | c.9934G>A p.V3312M | Missense Mutation (SNP) | VAF 265/379 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs746336789, COSV58061346; called by muse, mutect2, varscan2
- PRMT8 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 176/304 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs766069538, COSV54212649; called by muse, mutect2, varscan2
- PROCA1 | c.824C>A p.P275H (on ENST00000439862 / NM_001366301.1; = p.P247H on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/386 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV99972429; called by muse, mutect2, varscan2
- PRPF38A | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 141/347 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV99933084; called by muse, mutect2, varscan2
- PRPF38B | c.1461dup p.R488Tfs*4 | Frame Shift Ins (INS) | VAF 59/150 reads (39%) | catalogued as rs773200657; called by mutect2, varscan2
- PRPF40B | c.1018C>T p.R340W (on ENST00000380281; = p.R334W on NM_012272.3) | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746174120, COSV56061125, COSV99979152; called by muse, mutect2, varscan2
- PRPH | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV57679187; called by muse, mutect2
- PRR5-ARHGAP8 | c.1262del p.P421Lfs*3 (on ENST00000352766; = p.P342Lfs*3 on NM_181334.5) | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | catalogued as COSV100424356; called by mutect2, pindel, varscan2
- PRR5L | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237970347, COSV100286809; called by muse, mutect2
- PRRC2B | c.5270C>T p.A1757V | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV57646248; called by muse, mutect2, varscan2
- PRRC2C | c.1394G>A p.R465H (on ENST00000367742; = p.R463H on NM_015172.4) | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58913237; called by muse, mutect2, varscan2
- PTCH2 | c.1555G>A p.V519I | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs113543298, COSV100941834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN23 | c.3040dup p.L1014Pfs*68 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | catalogued as rs770411657; called by mutect2, varscan2
- PTPN5 | c.149A>G p.Q50R | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV62125760; called by muse, varscan2
- PTPRC | c.124A>G p.S42G | Missense Mutation (SNP) | VAF 143/378 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.721); catalogued as COSV100721928, COSV61406967; called by muse, mutect2, varscan2
- PTPRC | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 164/416 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1417710516, COSV100721929, COSV61411009; called by muse, mutect2, varscan2
- PTPRK | c.2066A>T p.D689V | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100950053; called by muse, mutect2, varscan2
- PTPRM | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 197/505 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100153784; called by muse, mutect2, varscan2
- PTPRM | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.088); catalogued as rs770279168, COSV59848745; called by muse, mutect2, varscan2
- PTPRU | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs757579431, COSV60530658; called by muse, mutect2, varscan2
- PUM1 | c.2539C>T p.R847W | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775876971, COSV57082236; called by muse, mutect2, varscan2
- PXDN | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53226833; called by muse, mutect2, varscan2
- RAB37 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs773776531, COSV100462394; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs770859492, COSV99424266; called by muse, mutect2, varscan2
- RABGAP1L | c.1514G>A p.C505Y | Missense Mutation (SNP) | VAF 142/422 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99266354; called by muse, mutect2, varscan2
- RAD51AP2 | c.1276dup p.T426Nfs*2 | Frame Shift Ins (INS) | VAF 32/88 reads (36%) | catalogued as rs759722299; called by mutect2, varscan2
- RALBP1 | c.124T>C p.Y42H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99191857; called by muse, varscan2
- RASGEF1A | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.117); catalogued as rs764016510, COSV100988613; called by muse, mutect2, varscan2
- RBM15B | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100081834, COSV60040760; called by muse, mutect2, varscan2
- RBM27 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 98/256 reads (38%) | catalogued as COSV54587672; called by muse, mutect2, varscan2
- RBM34 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs909374532, COSV64012778; called by muse, mutect2, varscan2
- RBM45 | c.122T>G p.L41R | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99617382; called by muse, mutect2, varscan2
- RCC2 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100965093; called by muse, mutect2, varscan2
- RCSD1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV100827497; called by muse, mutect2, varscan2
- RFFL | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1444080156, COSV99265094; called by muse, mutect2, varscan2
- RIMS1 | c.3596del p.P1199Qfs*46 | Frame Shift Del (DEL) | VAF 49/130 reads (38%) | catalogued as COSV53438532; called by mutect2, pindel, varscan2
- RNASEH2A | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 155/378 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV55551149; called by muse, mutect2, varscan2
- RNF113B | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1287434043, COSV99940240; called by muse, mutect2, varscan2
- RNF123 | c.1629+1del | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | catalogued as COSV59688684; called by mutect2, pindel, varscan2
- ROBO2 | c.332T>A p.V111D | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59933835; called by muse, mutect2, varscan2
- RPAP2 | c.1607T>A p.V536D | Missense Mutation (SNP) | VAF 129/341 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101528644; called by muse, mutect2, varscan2
- RPTOR | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); catalogued as rs768126116, COSV60815685; called by muse, mutect2, varscan2
- RPTOR | c.3622C>T p.R1208W | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs1034257924, COSV100154544; called by muse, mutect2, varscan2
- RSPO3 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 103/260 reads (40%) | catalogued as rs200509277, COSV100759428; called by muse, mutect2, varscan2
- RTN2 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1271589894, COSV55595576; called by muse, mutect2
- RYR1 | c.9905del p.P3302Hfs*19 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs749656679; called by mutect2, pindel
- SAGE1 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 85/100 reads (85%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61013035, COSV61018450; called by muse, mutect2, varscan2
- SCN2A | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs551347418, COSV51853101; called by muse, mutect2, varscan2
- SCN4A | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs369830835, COSV71127154; called by muse, mutect2, varscan2
- SEMA4G | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774063487, COSV52966041; called by muse, mutect2, varscan2
- SEPTIN4 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772182274, COSV57898217; called by muse, mutect2, varscan2
- SERBP1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as rs745628272, COSV100769025; called by muse, mutect2, varscan2
- SERTAD2 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 86/207 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs755073979, COSV100512047; called by muse, mutect2, varscan2
- SESN3 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV99565124; called by muse, mutect2, varscan2
- SETDB2 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 91/230 reads (40%) | catalogued as rs752831641, COSV99320406; called by muse, mutect2, varscan2
- SEZ6L2 | c.1270G>A p.D424N (on ENST00000308713 / NM_001114099.3; = p.D354N on NM_012410.4) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.468); catalogued as rs547134098, COSV58104129; called by muse, mutect2, varscan2
- SFRP1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55174909, COSV55176505; called by muse, mutect2
- SGSM2 | c.1654-2A>G p.X552_splice (on ENST00000426855 / NM_001098509.2; = p.X597_splice on NM_014853.3) | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99279559; called by muse, mutect2, varscan2
- SH3RF3 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs376984287; called by muse, mutect2, varscan2
- SHANK1 | c.2644C>T p.P882S | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV99519800; called by muse, mutect2, varscan2
- SIDT2 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 113/272 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.22); catalogued as rs956801595, COSV54060789; called by muse, mutect2, varscan2
- SIGLEC1 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs564843501, COSV52460473; called by muse, varscan2
- SIGLEC10 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs754521676, COSV100218334; called by muse, mutect2, varscan2
- SIRT2 | c.568T>G p.F190V | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99979094; called by muse, mutect2, varscan2
- SLC12A1 | c.2628del p.D877Mfs*46 | Frame Shift Del (DEL) | VAF 43/182 reads (24%) | catalogued as rs1419151341, COSV66797187; called by mutect2, pindel, varscan2
- SLC16A1 | c.825del p.F275Lfs*37 | Frame Shift Del (DEL) | VAF 84/225 reads (37%) | catalogued as rs150151185; called by mutect2, pindel, varscan2
- SLC16A1 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.447); catalogued as COSV100855740; called by muse, mutect2, varscan2
- SLC16A7 | c.786del p.F262Lfs*39 | Frame Shift Del (DEL) | VAF 64/270 reads (24%) | catalogued as COSV53899988; called by mutect2, pindel, varscan2
- SLC1A1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 118/374 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs199857691, COSV99261015; called by muse, varscan2
- SLC20A2 | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV100645951, COSV60604884; called by muse, mutect2, varscan2
- SLC22A6 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150409056, COSV64561181; called by muse, mutect2, varscan2
- SLC25A6 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs1369618113, COSV101195390; called by muse, mutect2, varscan2
- SLC2A14 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV100533372; called by muse, mutect2, varscan2
- SLC35F5 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV99829873; called by muse, mutect2, varscan2
- SLC37A2 | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as rs773920448, COSV100016808; called by muse, mutect2, varscan2
- SLC39A7 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1202409452, COSV63002249; called by muse, mutect2, varscan2
- SLC41A3 | c.1034G>A p.S345N | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV100259219; called by muse, varscan2
- SLC4A2 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs761077150, COSV59656111; called by muse, mutect2, varscan2
- SLC6A13 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446181233, COSV100569644, COSV58255447; called by muse, mutect2
- SLC6A3 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.747); catalogued as rs150576860; called by muse, mutect2, varscan2
- SLC8A3 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs755672807, COSV100775783; called by muse, mutect2, varscan2
- SLF2 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99488196; called by muse, mutect2, varscan2
- SLF2 | c.1106A>T p.H369L | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV99488204; called by muse, mutect2, varscan2
- SLPI | c.306del p.N103Ifs*13 | Frame Shift Del (DEL) | VAF 75/221 reads (34%) | catalogued as rs745834619; called by mutect2, pindel, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 77/225 reads (34%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SMCHD1 | c.2040del p.K680Nfs*3 | Frame Shift Del (DEL) | VAF 92/267 reads (34%) | catalogued as rs766211852; called by mutect2, varscan2
- SNRNP200 | c.3689G>T p.S1230I | Missense Mutation (SNP) | VAF 97/235 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100106750; called by muse, mutect2, varscan2
- SNRNP35 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781256349, COSV100644527; called by muse, mutect2, varscan2
- SNRPA | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs750727750, COSV99698674; called by muse, mutect2, varscan2
- SNX1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99975774; called by muse, mutect2, varscan2
- SOHLH2 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 106/257 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764959799, COSV65901489, COSV65904110; called by muse, mutect2, varscan2
- SORBS1 | c.3466G>A p.V1156M | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as rs772386830, COSV53367631; called by muse, mutect2, varscan2
- SOX10 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62806470, COSV62807596; called by muse, mutect2, varscan2
- SPAG16 | c.335T>G p.F112C | Missense Mutation (SNP) | VAF 308/796 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99793237; called by muse, mutect2, varscan2
- SPAG17 | c.282del p.K94Nfs*3 | Frame Shift Del (DEL) | VAF 62/245 reads (25%) | catalogued as rs771461785; called by mutect2, pindel, varscan2
- SPATA20 | c.971G>A p.R324H (on ENST00000356488 / NM_001258372.1; = p.R340H on NM_022827.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs368022155; called by muse, mutect2
- SPATA9 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99174118; called by muse, varscan2
- SPG21 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs756437687, COSV99200174; called by muse, mutect2, varscan2
- SPI1 | c.297del p.M100Wfs*86 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs1265596655, COSV99908809; called by mutect2, pindel, varscan2
- SPPL2C | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as rs774363885, COSV61291952; called by muse, mutect2, varscan2
- SPTB | c.6880C>T p.R2294C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.39); catalogued as rs770384233, COSV99906093; called by muse, mutect2, varscan2
- SPTBN2 | c.5341G>A p.E1781K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777756110, COSV100017840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN5 | c.9520C>T p.R3174W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs780341578, COSV100310308; called by muse, mutect2, varscan2
- SRP68 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 118/369 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs746905444, COSV57164854; called by muse, mutect2, varscan2
- SRPK1 | c.1197C>A p.S399R | Missense Mutation (SNP) | VAF 334/766 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV100644212; called by muse, mutect2, varscan2
- SRPRA | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs558045090, COSV99702382; called by muse, mutect2, varscan2
- SSBP4 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99525888; called by muse, mutect2
- SSH1 | c.2656G>A p.A886T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs190071016; called by muse, mutect2, varscan2
- ST18 | c.2876G>A p.S959N | Missense Mutation (SNP) | VAF 390/592 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs1372301516, COSV99387498; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 39/103 reads (38%) | PolyPhen benign (0.086); catalogued as COSV99336156; called by muse, mutect2, varscan2
- STAB1 | c.7043C>T p.A2348V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as rs1303995830, COSV100194390; called by muse, mutect2, varscan2
- STAB2 | c.3154T>A p.S1052T | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as COSV101185536; called by muse, mutect2, varscan2
- STAC2 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100336225, COSV61065623; called by muse, mutect2, varscan2
- STRAP | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 80/294 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs752651730, COSV99214598; called by muse, mutect2, varscan2
- STX11 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.427); catalogued as rs865966109, COSV100845452; called by muse, mutect2, varscan2
- STXBP1 | c.656T>C p.M219T | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as COSV64815053; called by muse, varscan2
- SULF1 | c.2008A>G p.R670G | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.893); catalogued as COSV99481577; called by muse, varscan2
- SV2A | c.412del p.E138Rfs*39 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | catalogued as rs1553764068; called by mutect2, pindel
- SVEP1 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 164/794 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV100236702, COSV57050561; called by muse, mutect2, varscan2
- SWSAP1 | c.274C>A p.L92I (on ENST00000312423; = p.L113I on NM_175871.4) | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775368458, COSV99710001; called by muse, mutect2, varscan2
- SYCP1 | c.2792del p.K931Rfs*6 | Frame Shift Del (DEL) | VAF 35/96 reads (36%) | catalogued as COSV101050748; called by mutect2, pindel, varscan2
- SYDE2 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as rs752386902, COSV99320103; called by muse, mutect2, varscan2
- SYK | c.496dup p.M166Nfs*14 | Frame Shift Ins (INS) | VAF 128/430 reads (30%) | catalogued as rs1433438204; called by pindel, varscan2
- SYNDIG1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV65234813; called by muse, mutect2, varscan2
- SYNE1 | c.22520G>A p.R7507H (on ENST00000367255 / NM_182961.4; = p.R7436H on NM_033071.3) | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776733924, COSV55059207; called by muse, mutect2, varscan2
- SZT2 | c.3689C>T p.A1230V (on ENST00000634258 / NM_001365999.1; = p.A1173V on NM_015284.4) | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as rs553638915, COSV65169454; called by muse, mutect2, varscan2
- SZT2 | c.8635C>T p.R2879C (on ENST00000634258 / NM_001365999.1; = p.R2822C on NM_015284.4) | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs769509671, COSV65172089; called by muse, mutect2, varscan2
- TAF3 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs768404137, COSV100719739; called by muse, mutect2, varscan2
- TAGAP | c.2131C>T p.R711* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV57851534; called by muse, mutect2, varscan2
- TAOK2 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 151/411 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs781600192, COSV54234458; called by muse, mutect2, varscan2
- TARBP1 | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs374573385; called by muse, mutect2, varscan2
- TAS2R14 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 101/170 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV101113743; called by muse, mutect2, varscan2
- TATDN2 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs576056241, COSV55051715, COSV99813161; called by muse, mutect2, varscan2
- TBC1D9 | c.3316G>A p.V1106M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs545624117, COSV71308588; called by muse, mutect2, varscan2
603 further variants in this file (262 protein-altering or splice-affecting, 321 silent, 20 other) are not listed here.
